Somatic mutation profile of tumor specimen TCGA-BR-7959-01A (aliquot TCGA-BR-7959-01A-11D-2340-08) from TCGA case TCGA-BR-7959, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 59.5 years (21,730 days).
Specimen TCGA-BR-7959-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b42c09e8-ab12-4f89-aa3c-a86289232c46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-7959-10A (Blood Derived Normal), aliquot TCGA-BR-7959-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4097cb40-9b57-40ca-b4f7-9665d3f42eb0

The open-access MAF lists 97 somatic variants for this specimen: 78 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 17, Nonsense Mutation 6, Frame Shift Del 1, Intron 1, Splice Region 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL121899.2 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 87/187 reads (47%) | catalogued as rs779702016, COSV67349709; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD8 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV53112549; called by muse, mutect2
- ACADSB | c.185T>C p.M62T | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV62550305; called by muse, mutect2, varscan2
- ANK1 | c.4025T>C p.F1342S | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV55872838; called by muse, mutect2, varscan2
- ARFGEF2 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs566630105, COSV64210462; called by muse, mutect2, varscan2
- ARL6IP1 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV58614052; called by muse, mutect2, varscan2
- ARMCX1 | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.048); catalogued as COSV65704875; called by muse, mutect2, varscan2
- ATF7IP | c.2756C>A p.S919* | Nonsense Mutation (SNP) | VAF 43/87 reads (49%) | catalogued as COSV53766288, COSV53777637; called by muse, mutect2, varscan2
- BUD31 | c.206C>G p.A69G | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV99463197; called by muse, mutect2, varscan2
- CASP5 | c.570C>G p.D190E | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.067); catalogued as COSV52826627; called by muse, mutect2, varscan2
- CATSPERD | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as rs530421612, COSV58464254; called by muse, mutect2, varscan2
- CCDC83 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1476523567, COSV54699730; called by muse, mutect2, varscan2
- CDH23 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.428); catalogued as rs562019725, COSV54924513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL22A1 | c.2924C>A p.P975H | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57323227; called by muse, mutect2, varscan2
- CSF3R | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs186379741, COSV58963281, COSV58964038; called by muse, mutect2, varscan2
- CTSV | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.031); catalogued as COSV52344020; called by muse, mutect2
- DCHS1 | c.4877C>G p.S1626C | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.869); catalogued as rs754913718, COSV100202563, COSV55030556; called by muse, mutect2, varscan2
- DHRS7C | c.95A>C p.K32T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV57649630; called by muse, mutect2, varscan2
- EHMT1 | c.3688C>T p.R1230C | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs61744215, COSV66044562; ClinVar: uncertain significance; called by muse, mutect2
- ELFN2 | c.65C>G p.A22G | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV68743805; called by muse, mutect2
- ETAA1 | c.1193A>G p.D398G | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV55472019; called by muse, mutect2, varscan2
- EVC | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs754239541, COSV53829253; called by muse, mutect2, varscan2
- FREM1 | c.2340G>A p.A780= | Splice Region (SNP) | VAF 3/15 reads (20%) | catalogued as rs140837413; called by muse, mutect2
- FRYL | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as rs752955969, COSV51940309; called by muse, mutect2, varscan2
- GBF1 | c.1219G>A p.E407K (on ENST00000369983 / NM_001377137.1; = p.E406K on NM_004193.3) | Missense Mutation (SNP) | VAF 36/598 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1329959630, COSV64142807; called by muse, mutect2
- GIGYF2 | c.3584G>A p.R1195H | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs748828699, COSV65246524; called by muse, mutect2, varscan2
- HSD11B1L | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56797635; called by muse, mutect2, varscan2
- ID1 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1231671714, COSV65888297; called by muse, mutect2, varscan2
- INTS4 | c.1675C>G p.P559A | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV71087119; called by muse, mutect2, varscan2
- IRAK4 | c.67T>A p.S23T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV71210279; called by muse, mutect2, varscan2
- KCNG1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.166); catalogued as COSV65367957; called by muse, mutect2, varscan2
- KIF27 | c.2240G>T p.G747V | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52825065; called by muse, mutect2
- KLHL23 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs1034913081, COSV55865678; called by muse, mutect2, varscan2
- LCP1 | c.1289A>G p.Y430C | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59939394; called by muse, mutect2, varscan2
- LRFN2 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139033638; called by muse, mutect2, varscan2
- LRP1B | c.4844C>T p.A1615V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs765212179, COSV67183180, COSV67186670; called by muse, mutect2, varscan2
- MAN2B1 | c.785A>G p.N262S | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as rs944317989, COSV55470088; called by muse, mutect2, varscan2
- MAP2K7 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs774212941, COSV67607603; called by muse, mutect2, varscan2
- MATN2 | c.869G>A p.C290Y | Missense Mutation (SNP) | VAF 107/289 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54706809; called by muse, mutect2, varscan2
- MSH6 | c.806C>G p.T269S | Missense Mutation (SNP) | VAF 32/317 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs587779322, COSV52274271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSR1 | c.1047A>C p.K349N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV50506842; called by muse, mutect2
- MTUS2 | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764265852, COSV70913437; called by muse, mutect2, varscan2
- MUC16 | c.5304T>G p.F1768L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV67444959; called by muse, mutect2, varscan2
- MYO1F | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1013283787, COSV57791860; called by muse, mutect2, varscan2
- NAV3 | c.5689T>A p.S1897T (on ENST00000397909 / NM_001024383.2; = p.S1875T on NM_014903.6) | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.554); catalogued as COSV57061938, COSV57079842; called by muse, mutect2, varscan2
- NCAM2 | c.2349A>C p.E783D | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.13); catalogued as COSV53056548, COSV99526219; called by muse, mutect2, varscan2
- OBSL1 | c.1717G>A p.G573R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370809389; called by mutect2, varscan2
- OPLAH | c.1579G>A p.V527M | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375093557; called by muse, mutect2, varscan2
- OR13G1 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as COSV62943372; called by muse, mutect2, varscan2
- OTUD6A | c.298A>T p.R100* | Nonsense Mutation (SNP) | VAF 16/25 reads (64%) | catalogued as COSV57972644; called by muse, mutect2, varscan2
- OXR1 | c.854C>T p.S285F (on ENST00000442977 / NM_001198532.1; = p.S284F on NM_018002.3) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs1042637479, COSV56324325; called by muse, mutect2, varscan2
- PCDHB15 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as rs782451446, COSV50858541; called by muse, mutect2, varscan2
- PDE3B | c.1323C>G p.S441R | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1460591854, COSV56379693; called by muse, mutect2, varscan2
- PHKA1 | c.3653G>A p.S1218N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.284); catalogued as COSV59801782; called by muse, mutect2, varscan2
- POM121L12 | c.375T>A p.C125* | Nonsense Mutation (SNP) | VAF 17/98 reads (17%) | catalogued as COSV101374946, COSV68692210; called by muse, mutect2, varscan2
- POP4 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV55675878; called by muse, varscan2
- PRB2 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 26/560 reads (5%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.065); catalogued as COSV66982168; called by muse, mutect2
- PRKCG | c.601A>T p.I201F | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV54723844; called by muse, mutect2, varscan2
- SCN2A | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51832357; called by muse, mutect2, varscan2
- SLC35F2 | c.782T>A p.I261N | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs779040801, COSV56181928; called by muse, mutect2, varscan2
- STPG2 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54785488; called by muse, mutect2, varscan2
- SUPT20H | c.4-1G>A p.X2_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as COSV62246753; called by muse, varscan2
- TENM4 | c.6641G>A p.R2214H | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767106649, COSV53608656; called by muse, mutect2, varscan2
- THSD7B | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs539697788, COSV55654615; called by muse, mutect2, varscan2
- TMEM132D | c.1539C>A p.S513R | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs775382777, COSV67158722; called by muse, mutect2, varscan2
- TRIO | c.3693C>A p.F1231L | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60077599, COSV60082357; called by muse, mutect2, varscan2
- UBAP2L | c.2680C>T p.Q894* | Nonsense Mutation (SNP) | VAF 60/183 reads (33%) | catalogued as COSV55167736; called by muse, mutect2, varscan2
- UNC13C | c.3368G>A p.R1123K | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV52847647; called by muse, mutect2
- ZBTB34 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 28/287 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1056024913, COSV59859357; called by muse, mutect2, varscan2
- ZC3HC1 | c.1217G>C p.C406S | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.145); catalogued as COSV61297193; called by muse, mutect2
- ZNF35 | c.402A>C p.K134N | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV56075869, COSV56077043; called by muse, mutect2, varscan2
- ZNF382 | c.1505G>C p.S502T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV53086051; called by muse, mutect2, varscan2
- ZNF423 | c.2132C>T p.S711L (on ENST00000563137 / NM_001379286.1; = p.S703L on NM_015069.4) | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs144284315; called by muse, mutect2, varscan2
- ZNF512 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as COSV62673785; called by muse, mutect2, varscan2
- ZNF780A | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61814518; called by muse, mutect2
- ZNF91 | c.3107A>C p.K1036T | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.103); catalogued as rs1243370351, COSV56080410; called by muse, mutect2, varscan2
- TRGV8 | c.98C>G p.T33S | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.177); called by muse, mutect2
- VCPIP1 | c.3324del p.K1108Nfs*37 | Frame Shift Del (DEL) | VAF 18/127 reads (14%) | called by mutect2, pindel, varscan2
- CNTROB | c.1401G>A p.Q467= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV66607509; called by muse, mutect2, varscan2
- CTR9 | c.2850G>A p.E950= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV63727781; called by muse, mutect2, varscan2
- EVPL | c.5997C>T p.R1999= | Silent (SNP) | VAF 72/160 reads (45%) | catalogued as COSV56907375; called by muse, mutect2, varscan2
- GLYCTK | c.1569G>A p.R523= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs1316735590, COSV59793051; called by muse, mutect2, varscan2
- HYDIN | c.11229C>T p.P3743= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs376228603; called by muse, mutect2, varscan2
- ITGA7 | c.2982C>T p.C994= (on ENST00000555728; = p.C950= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs374984482, COSV57701541; called by muse, mutect2
- KRT40 | c.1218G>C p.S406= | Silent (SNP) | VAF 84/204 reads (41%) | catalogued as COSV66695978; called by muse, mutect2, varscan2
- MCAM | c.906C>T p.N302= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs1344268035, COSV50629964; called by muse, mutect2, varscan2
- MDN1 | c.14769G>A p.E4923= | Silent (SNP) | VAF 27/124 reads (22%) | catalogued as COSV65517197, COSV65523272; called by muse, mutect2, varscan2
- NEK7 | c.438C>T p.C146= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as COSV66314159; called by muse, mutect2, varscan2
- RNF213 | c.13263G>A p.S4421= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as rs529614263, COSV60390175; called by muse, mutect2, varscan2
- SFRP1 | c.552G>A p.T184= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs978013726, COSV55171964; called by muse, mutect2, varscan2
- SLC24A3 | c.1593T>C p.I531= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as rs930545824, COSV60111668; called by muse, mutect2, varscan2
- SLC24A4 | c.846C>T p.S282= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV54107224; called by muse, mutect2, varscan2
- TOP3B | c.1953G>A p.T651= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs748637983, COSV64116369; called by muse, mutect2, varscan2
- ZNF134 | c.1029G>A p.P343= | Silent (SNP) | VAF 31/260 reads (12%) | catalogued as rs370054183; called by muse, varscan2
- ZNF343 | c.723C>T p.I241= | Silent (SNP) | VAF 61/121 reads (50%) | catalogued as COSV53852450; called by muse, mutect2, varscan2
- RIMS2 | c.2197-3392T>G | Intron (SNP) | VAF 10/21 reads (48%) | catalogued as COSV51653367; called by muse, mutect2, varscan2
- TMEM132E | chr17:34579218 G>A | 5'Flank (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2
